Somatic mutation profile of tumor specimen TCGA-27-1837-01A (aliquot TCGA-27-1837-01A-01D-1494-08) from TCGA case TCGA-27-1837, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.6 years (13,368 days).
Specimen TCGA-27-1837-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcc35f9a-bed5-422b-8528-47aaa7b1402a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1837-10A (Blood Derived Normal), aliquot TCGA-27-1837-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cad1584c-d5d0-40ec-8825-8d5af56de233

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.11049C>A p.S3683R | Missense Mutation (SNP) | VAF 119/266 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71284479; called by muse, mutect2, varscan2
- ABCA5 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67016024; called by muse, mutect2, varscan2
- ADAMTS15 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs748790827, COSV54503801; called by muse, mutect2, varscan2
- ALPG | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs778702552, COSV54965299; called by muse, mutect2, varscan2
- CCDC12 | c.286G>A p.E96K (on ENST00000425441 / NM_001277074.1; = p.E109K on NM_144716.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.387); catalogued as rs566710688, COSV52765163; called by muse, mutect2, varscan2
- COL26A1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs772822189, COSV58121667, COSV58128628; called by muse, mutect2, varscan2
- CYP4X1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.668); catalogued as rs753837465, COSV64149903; called by muse, mutect2, varscan2
- DPYSL5 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV56509653; called by muse, mutect2, varscan2
- ENPEP | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1489093019, COSV54447993; called by muse, mutect2, varscan2
- FBXL13 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.09); catalogued as rs180901632, COSV57535706; called by muse, mutect2, varscan2
- FDPS | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs1432292015, COSV63113988; called by muse, mutect2, varscan2
- GLTP | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 166/421 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as COSV59172528; called by muse, mutect2, varscan2
- INIP | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV65295258; called by muse, mutect2, varscan2
- MUC5AC | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); catalogued as rs773114226, COSV62253478; called by muse, mutect2, varscan2
- NCOR1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV51964795; called by muse, mutect2, varscan2
- OR4D5 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746149575, COSV58306026; called by muse, mutect2, varscan2
- PCDHGA11 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53912590; called by muse, mutect2, varscan2
- PCDHGB2 | c.1025A>C p.D342A | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53912579; called by muse, mutect2, varscan2
- RELN | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 47/169 reads (28%) | catalogued as COSV58990404; called by muse, mutect2, varscan2
- RFPL1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs748957165, COSV62977497; called by muse, mutect2, varscan2
- SEMA3C | c.325A>C p.T109P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as rs13310887, COSV54843027; called by muse, mutect2, varscan2
- SETDB1 | c.3766C>T p.R1256W (on ENST00000271640 / NM_001366417.1; = p.R1255W on NM_012432.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1395729846, COSV54976407; called by muse, mutect2, varscan2
- SLC4A1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as rs201280873; called by muse, mutect2, varscan2
- SLC9C1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- SOX14 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV60162553; called by muse, mutect2, varscan2
- TPR | c.3812T>C p.V1271A | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV66599962; called by muse, mutect2, varscan2
- TUBA1A | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV55496989, COSV55498595; called by muse, varscan2
- UGT2B28 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59431034; called by muse, mutect2, varscan2
- WDR81 | c.4138C>G p.L1380V (on ENST00000409644 / NM_001163809.2; = p.L329V on NM_152348.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV58479364; called by muse, mutect2, varscan2
- ZNF48 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141362652; called by muse, mutect2, varscan2
- CLDN14 | c.600C>T p.A200= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV59772247; called by muse, mutect2, varscan2
- CLSTN3 | c.2175C>T p.L725= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs774966830, COSV56934571; called by muse, mutect2, varscan2
- GRM3 | c.843G>A p.S281= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100862169, COSV64468578; called by muse, mutect2, varscan2
- OR5H1 | c.309G>A p.S103= | Silent (SNP) | VAF 130/348 reads (37%) | catalogued as rs779446848, COSV63401624, COSV63401900; called by muse, mutect2, varscan2
- PCDHB15 | c.1659C>T p.D553= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV50858046; called by muse, mutect2, varscan2
- SPIN2B | c.366C>T p.A122= | Silent (SNP) | VAF 117/166 reads (70%) | catalogued as COSV52068751; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2712A>G p.E904= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as COSV60155902; called by muse, mutect2, varscan2
- SKA2 | c.33+130C>T | Intron (SNP) | VAF 33/97 reads (34%) | catalogued as rs755480328, COSV99231307; called by muse, mutect2, varscan2
